Somatic mutation profile of tumor specimen C3L-05362-02 (aliquot CPT0341310006) from CPTAC case C3L-05362, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 67.9 years (24,806 days).
Specimen C3L-05362-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0c71d73-0401-4fed-90ac-c6db549ec2bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05362-31 (Blood Derived Normal), aliquot CPT0341460002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9dabdbb6-af1d-43b3-9f9f-f2c6095a1258

The open-access MAF lists 220 somatic variants for this specimen: 138 protein-altering or splice-affecting, 74 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 74, Nonsense Mutation 7, Intron 5, Splice Region 2, 5'UTR 2, 3'UTR 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/310 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- RET | c.2711C>T p.S904F | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267607011, CM020379, CM076454, COSV60690751, COSV60693575; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM18 | c.1852C>T p.H618Y | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.296); catalogued as rs866076661, COSV55845988; called by muse, mutect2, varscan2
- ADCYAP1 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV52486087; called by muse, mutect2, varscan2
- AFP | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as COSV56924389; called by muse, mutect2
- ANOS1 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV52926023; called by muse, mutect2
- B3GNT3 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 58/409 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as rs949440340; called by muse, mutect2, varscan2
- BIN1 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1485180311; called by muse, mutect2, varscan2
- BMP7 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 48/564 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1186663823; ClinVar: uncertain significance; called by muse, mutect2
- CDH6 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 56/388 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV54063332; called by muse, mutect2, varscan2
- CHRM3 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 46/361 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55098720, COSV99698736; called by muse, mutect2, varscan2
- CSMD2 | c.10321C>T p.P3441S | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.576); catalogued as rs1025727891; called by muse, mutect2, varscan2
- DEFB119 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 33/310 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV53619739; called by muse, mutect2, varscan2
- DNAH12 | c.6962G>A p.R2321Q (on ENST00000351747; = p.R3189Q on NM_001366028.2) | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.038); catalogued as rs1198708530; called by muse, mutect2, varscan2
- DPP6 | c.1099G>A p.D367N (on ENST00000377770 / NM_001364500.2; = p.D305N on NM_001936.5) | Missense Mutation (SNP) | VAF 42/345 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV100127949; called by muse, mutect2, varscan2
- EYS | c.6613C>T p.L2205F | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1290357542, COSV101008493, COSV101011693; called by muse, mutect2, varscan2
- GHR | c.612G>A p.W204* | Nonsense Mutation (SNP) | VAF 16/198 reads (8%) | catalogued as COSV50109797; called by muse, mutect2
- GRXCR1 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 39/370 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as COSV67670228; called by muse, mutect2, varscan2
- HDAC3 | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 32/269 reads (12%) | catalogued as COSV59498291; called by muse, mutect2, varscan2
- IGHV4-28 | c.15G>T p.W5C | Missense Mutation (SNP) | VAF 32/594 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs373522924; called by muse, mutect2
- IGSF9 | c.2747C>T p.P916L (on ENST00000368094 / NM_001135050.2; = p.P900L on NM_020789.4) | Missense Mutation (SNP) | VAF 63/502 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57422496; called by muse, mutect2, varscan2
- INTS6L | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 31/339 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100878324; called by muse, mutect2
- ITIH5 | c.2693G>A p.G898E | Missense Mutation (SNP) | VAF 48/381 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751345630; called by muse, mutect2, varscan2
- ITIH5 | c.2158G>A p.V720M | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs753707640; called by muse, mutect2
- KBTBD13 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 42/311 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1308816311; called by muse, mutect2, varscan2
- KHDRBS2 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV55430948; called by muse, mutect2, varscan2
- KIAA1109 | c.11476C>T p.R3826* | Nonsense Mutation (SNP) | VAF 13/194 reads (7%) | catalogued as COSV99179971; called by muse, mutect2
- KIAA1217 | c.3098C>T p.S1033L | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs534553518, COSV56821317; called by muse, mutect2, varscan2
- KIF21B | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 30/429 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV59752123; called by muse, mutect2
- KRT26 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs867267799, COSV100053192; called by muse, mutect2
- LIFR | c.1891C>T p.L631F | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV54684166; called by muse, mutect2
- LMBRD2 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs752962680; called by muse, mutect2, varscan2
- MTMR8 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 74/485 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV66392865; called by muse, mutect2, varscan2
- MTRNR2L6 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 30/222 reads (14%) | PolyPhen benign (0.412); catalogued as rs567329518; called by muse, mutect2, varscan2
- MUC16 | c.11801C>T p.P3934L | Missense Mutation (SNP) | VAF 53/359 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as rs1421521085, COSV101200424; called by muse, mutect2, varscan2
- MYH11 | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 44/359 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs867589365, COSV55544471; called by muse, mutect2, varscan2
- MYOM2 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50704288; called by muse, mutect2, varscan2
- NBEA | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 13/341 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV59815167; called by muse, mutect2
- NDST4 | c.2533C>T p.H845Y | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV52121706; called by muse, mutect2
- NEB | c.3045C>T p.I1015= | Splice Region (SNP) | VAF 20/232 reads (9%) | catalogued as rs773307085, COSV50857038; called by muse, mutect2
- NEFM | c.1574G>A p.G525E | Missense Mutation (SNP) | VAF 68/501 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs778197595; called by muse, mutect2, varscan2
- NFKBIE | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 68/578 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1396486702; called by muse, mutect2, varscan2
- NHLRC3 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs376395095; called by muse, mutect2, varscan2
- NOL8 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as rs759194714, COSV100694470; called by muse, mutect2, varscan2
- NOTCH1 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1286892980, COSV53028502; called by muse, varscan2
- NOX1 | c.27G>A p.W9* | Nonsense Mutation (SNP) | VAF 42/373 reads (11%) | catalogued as COSV54194342; called by muse, mutect2, varscan2
- OBSCN | c.12970C>T p.H4324Y | Missense Mutation (SNP) | VAF 43/368 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV52828004; called by muse, mutect2, varscan2
- OLFML2B | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 60/455 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs142774017; called by muse, mutect2, varscan2
- OR10G7 | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 61/550 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100389819, COSV57867545; called by muse, mutect2, varscan2
- OR4A8 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); catalogued as rs1326805338; called by muse, mutect2, varscan2
- OR51V1 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 51/350 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.874); catalogued as rs1208956445, COSV58314692; called by muse, mutect2, varscan2
- OR5I1 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 45/332 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56886245; called by muse, mutect2, varscan2
- POF1B | c.1655G>A p.R552K | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs1217804788, COSV99426818, COSV99427308; called by muse, mutect2
- PRLR | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 44/380 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV51495842; called by muse, mutect2, varscan2
- PRPF8 | c.4355C>T p.P1452L | Missense Mutation (SNP) | VAF 44/407 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59268102; called by muse, mutect2, varscan2
- RAPGEF4 | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51386688; called by muse, mutect2, varscan2
- RNF20 | c.2668C>T p.R890C | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101206597; called by muse, mutect2, varscan2
- RP1 | c.3974G>A p.G1325E | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV55121289; called by muse, mutect2, varscan2
- RP1 | c.4271C>T p.S1424L | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs777328112; called by muse, mutect2
- SETX | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56385557; called by muse, mutect2, varscan2
- SFMBT2 | c.1461G>C p.K487N | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV62806844; called by muse, mutect2
- SHOX | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as CM080538; called by muse, mutect2, varscan2
- SLC9A2 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 42/403 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV52129528; called by muse, mutect2, varscan2
- TBX18 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 58/458 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs748500583; called by muse, mutect2, varscan2
- TTC22 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 15/430 reads (3%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV64881701; called by muse, mutect2
- TXLNB | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 41/269 reads (15%) | catalogued as rs866013283, COSV62727201; called by muse, mutect2, varscan2
- ZAN | c.5941G>A p.G1981S | Missense Mutation (SNP) | VAF 40/379 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.297); catalogued as rs1490139536; called by muse, mutect2, varscan2
- ZMAT4 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 48/369 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as rs867752388, COSV52704877; called by muse, mutect2, varscan2
- ZNF527 | c.749A>G p.D250G | Missense Mutation (SNP) | VAF 17/323 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1009419539; called by muse, mutect2
- ZNF578 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs1245367481, COSV69736448; called by muse, mutect2
- ACTG1 | c.1004G>C p.R335P | Missense Mutation (SNP) | VAF 31/372 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2
- AGBL1 | c.2933G>A p.G978E | Missense Mutation (SNP) | VAF 15/371 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- AHNAK2 | c.15283C>T p.P5095S | Missense Mutation (SNP) | VAF 53/393 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- AK2 | c.343A>G p.N115D (on ENST00000354858; = p.N157D on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2
- AKAP14 | c.261+5G>C | Splice Region (SNP) | VAF 14/314 reads (4%) | called by muse, mutect2
- ANGPTL1 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ANKAR | c.977T>G p.L326R | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ARID1B | c.5129C>T p.S1710F | Missense Mutation (SNP) | VAF 55/368 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ASB16 | c.68T>A p.L23Q | Missense Mutation (SNP) | VAF 57/396 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ATG5 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 17/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNA1H | c.2065C>A p.P689T | Missense Mutation (SNP) | VAF 31/501 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.156); called by muse, mutect2
- CCDC196 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CDH7 | c.796T>A p.S266T | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CFHR5 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.061); called by muse, mutect2
- CHTF18 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 54/579 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- COL4A5 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 52/355 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- COL5A1 | c.2773G>A p.G925S | Missense Mutation (SNP) | VAF 50/392 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A5 | c.5374G>A p.E1792K (on ENST00000312481; = p.E1788K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- CR1L | c.1594G>A p.G532R | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); called by muse, mutect2
- CUX2 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- DDHD2 | c.1006C>A p.Q336K | Missense Mutation (SNP) | VAF 45/343 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDR1 | c.1774C>T p.P592S (on ENST00000324771; = p.P555S on NM_001954.4) | Missense Mutation (SNP) | VAF 56/452 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH5 | c.7111C>T p.P2371S | Missense Mutation (SNP) | VAF 62/357 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- DOCK9 | c.4721G>A p.R1574K (on ENST00000376460 / NM_001366676.2; = p.R1575K on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- FAM135B | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GALR1 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 27/407 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- IARS2 | c.1897C>T p.Q633* | Nonsense Mutation (SNP) | VAF 43/329 reads (13%) | called by muse, mutect2, varscan2
- LRRC32 | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 60/505 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRD1 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MACROH2A1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 44/301 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOB3B | c.526A>G p.M176V | Missense Mutation (SNP) | VAF 44/371 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.7679C>T p.A2560V | Missense Mutation (SNP) | VAF 29/431 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- NOTCH1 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, varscan2
- NPAP1 | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 44/342 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- NUP107 | c.81T>G p.S27R | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OSBPL2 | c.87del p.V30Sfs*4 (on ENST00000313733 / NM_144498.4; = p.V18Sfs*4 on NM_014835.4) | Frame Shift Del (DEL) | VAF 49/368 reads (13%) | called by mutect2, pindel, varscan2
- OSBPL7 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2
- OSBPL7 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2
- PCLO | c.13267G>A p.D4423N | Missense Mutation (SNP) | VAF 13/491 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PELP1 | c.749T>G p.F250C | Missense Mutation (SNP) | VAF 31/399 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.747); called by muse, mutect2
- PHF8 | c.2071C>T p.R691C (on ENST00000357988 / NM_001184896.1; = p.R655C on NM_015107.3) | Missense Mutation (SNP) | VAF 51/346 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIK3C2G | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLEKHG7 | c.823A>G p.T275A | Missense Mutation (SNP) | VAF 55/328 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- POTEE | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 30/805 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- POTEF | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PREX2 | c.4174C>T p.P1392S | Missense Mutation (SNP) | VAF 39/309 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PROX1 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 50/498 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRB | c.5212C>T p.P1738S | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- RBP3 | c.809G>A p.R270K | Missense Mutation (SNP) | VAF 66/604 reads (11%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.987); called by muse, mutect2
- RFPL3 | c.388G>A p.D130N (on ENST00000249007 / NM_001098535.1; = p.D101N on NM_006604.2) | Missense Mutation (SNP) | VAF 26/335 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RGMA | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- RIMS1 | c.3901C>T p.R1301* | Nonsense Mutation (SNP) | VAF 36/323 reads (11%) | called by muse, mutect2, varscan2
- SCN2A | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 47/373 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SETD7 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 37/333 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMG7 | c.2547G>T p.M849I | Missense Mutation (SNP) | VAF 53/422 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- SMTNL2 | c.485C>A p.A162E (on ENST00000389313 / NM_001114974.2; = p.A18E on NM_198501.3) | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2
- SPANXN4 | c.197A>C p.Q66P | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2
- SPATA16 | c.1706G>A p.R569K | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- STK38L | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- TAF1 | c.1192G>A p.G398R (on ENST00000373790 / NM_138923.4; = p.G419R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/491 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TAOK1 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- TCP11X2 | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 57/862 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2
- TGFB3 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 38/534 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- THRA | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 55/410 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USH2A | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 47/355 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VGLL2 | c.941C>T p.S314F (on ENST00000326274 / NM_182645.3; = p.S140F on NM_153453.1) | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); called by muse, mutect2
- VWDE | c.4381C>T p.P1461S | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- ZNF385C | c.399+1G>A p.X133_splice | Splice Site (SNP) | VAF 31/309 reads (10%) | called by muse, mutect2, varscan2
- ABCB9 | c.1767C>T p.P589= (on ENST00000280560 / NM_019625.4; = p.P546= on NM_019624.3) | Silent (SNP) | VAF 36/388 reads (9%) | catalogued as rs373846386; called by muse, mutect2
- ACACA | c.4887C>T p.S1629= | Silent (SNP) | VAF 43/470 reads (9%) | called by muse, mutect2
- ADAMTS19 | c.858G>A p.E286= | Silent (SNP) | VAF 52/392 reads (13%) | catalogued as rs772048826; called by muse, mutect2
- ADCYAP1 | c.258G>A p.G86= | Silent (SNP) | VAF 29/261 reads (11%) | catalogued as rs1482590642; called by muse, mutect2, varscan2
- AGA | c.210C>T p.D70= | Silent (SNP) | VAF 41/396 reads (10%) | catalogued as rs762870187, COSV99219655; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALPK1 | c.148C>T p.L50= | Silent (SNP) | VAF 28/278 reads (10%) | called by muse, mutect2
- APBA1 | c.2373C>T p.I791= | Silent (SNP) | VAF 43/428 reads (10%) | called by muse, mutect2, varscan2
- ARHGAP17 | c.679T>C p.L227= | Silent (SNP) | VAF 47/272 reads (17%) | catalogued as rs750760129; called by muse, mutect2, varscan2
- ARVCF | c.501C>T p.F167= | Silent (SNP) | VAF 62/528 reads (12%) | catalogued as COSV54269925; called by muse, mutect2, varscan2
- B3GNT3 | c.288G>A p.Q96= | Silent (SNP) | VAF 59/412 reads (14%) | called by muse, mutect2, varscan2
- BMP7 | c.156G>A p.R52= | Silent (SNP) | VAF 48/570 reads (8%) | called by muse, mutect2
- C12orf56 | c.1608G>A p.V536= (on ENST00000543942 / NM_001170633.2; = p.V376= on NM_001099676.3) | Silent (SNP) | VAF 36/266 reads (14%) | called by muse, mutect2, varscan2
- C3 | c.2016C>T p.S672= | Silent (SNP) | VAF 21/476 reads (4%) | catalogued as rs1394781087, COSV55571386; called by muse, mutect2
- CARD11 | c.1293G>A p.L431= | Silent (SNP) | VAF 40/382 reads (10%) | catalogued as COSV101211052; called by muse, mutect2, varscan2
- CCHCR1 | c.282C>T p.I94= | Silent (SNP) | VAF 132/578 reads (23%) | catalogued as rs780859794, COSV66161129; called by muse, mutect2, varscan2
- CFTR | c.402G>A p.R134= | Silent (SNP) | VAF 51/376 reads (14%) | called by muse, mutect2, varscan2
- DNAH3 | c.3570G>A p.K1190= | Silent (SNP) | VAF 43/389 reads (11%) | catalogued as rs1425694087; called by muse, mutect2, varscan2
- DNAH8 | c.1299C>T p.I433= | Silent (SNP) | VAF 17/177 reads (10%) | catalogued as rs372590465; called by muse, mutect2, varscan2
- ESX1 | c.1017G>A p.V339= | Silent (SNP) | VAF 46/652 reads (7%) | called by muse, mutect2
- EVC2 | c.2091C>T p.F697= | Silent (SNP) | VAF 54/442 reads (12%) | called by muse, mutect2, varscan2
- FAAP100 | c.2301C>T p.I767= | Silent (SNP) | VAF 34/352 reads (10%) | catalogued as rs867227331, COSV59884996; called by muse, mutect2
- FAN1 | c.747G>A p.E249= | Silent (SNP) | VAF 26/560 reads (5%) | catalogued as COSV100756029; called by muse, mutect2
- FER1L6 | c.4269C>T p.I1423= | Silent (SNP) | VAF 34/311 reads (11%) | catalogued as COSV101205822; called by muse, mutect2, varscan2
- FGD5 | c.1711T>C p.L571= | Silent (SNP) | VAF 40/438 reads (9%) | called by muse, mutect2
- FLNC | c.798C>G p.A266= | Silent (SNP) | VAF 43/373 reads (12%) | called by muse, mutect2, varscan2
- GPC1 | c.378C>T p.F126= | Silent (SNP) | VAF 53/553 reads (10%) | catalogued as COSV50865691; called by muse, mutect2
- GPRIN3 | c.2013C>T p.S671= | Silent (SNP) | VAF 50/374 reads (13%) | called by muse, mutect2, varscan2
- IGSF5 | c.354G>T p.S118= | Silent (SNP) | VAF 20/384 reads (5%) | called by muse, mutect2
- INPP5E | c.1773C>T p.F591= | Silent (SNP) | VAF 42/392 reads (11%) | called by muse, mutect2, varscan2
- KCNA10 | c.870C>T p.F290= | Silent (SNP) | VAF 56/437 reads (13%) | catalogued as rs778646312, COSV63905424; called by muse, mutect2, varscan2
- KIAA2012 | c.1611G>A p.P537= | Silent (SNP) | VAF 37/291 reads (13%) | catalogued as rs1264483262; called by muse, mutect2, varscan2
- KLF6 | c.165C>T p.I55= | Silent (SNP) | VAF 42/349 reads (12%) | called by muse, mutect2, varscan2
- LMX1A | c.960G>A p.Q320= | Silent (SNP) | VAF 39/342 reads (11%) | catalogued as COSV99672839; called by muse, mutect2, varscan2
- LYPD4 | c.315C>T p.S105= | Silent (SNP) | VAF 19/456 reads (4%) | called by muse, mutect2
- MAGEA10 | c.643C>T p.L215= | Silent (SNP) | VAF 50/543 reads (9%) | catalogued as COSV54882743; called by muse, mutect2
- MGAM2 | c.1650C>T p.I550= | Silent (SNP) | VAF 35/308 reads (11%) | called by muse, mutect2
- MMD2 | c.693G>A p.R231= (on ENST00000404774 / NM_001100600.2; = p.R207= on NM_198403.4) | Silent (SNP) | VAF 49/403 reads (12%) | catalogued as rs1562473784; called by muse, mutect2, varscan2
- NEFM | c.1575G>A p.G525= | Silent (SNP) | VAF 67/498 reads (13%) | called by muse, mutect2, varscan2
- NUGGC | c.525G>A p.R175= | Silent (SNP) | VAF 48/448 reads (11%) | called by muse, mutect2
- OR13C8 | c.39C>T p.F13= | Silent (SNP) | VAF 35/403 reads (9%) | catalogued as rs758343445, COSV58610595; called by muse, mutect2
- OR4A15 | c.129C>T p.I43= | Silent (SNP) | VAF 43/405 reads (11%) | catalogued as COSV59034200; called by muse, mutect2, varscan2
- OXGR1 | c.855C>T p.I285= | Silent (SNP) | VAF 42/351 reads (12%) | catalogued as rs1240445214, COSV53657345; called by muse, mutect2, varscan2
- PCDHB7 | c.300G>A p.E100= | Silent (SNP) | VAF 41/345 reads (12%) | called by muse, mutect2, varscan2
- PEG3 | c.426C>T p.D142= | Silent (SNP) | VAF 65/308 reads (21%) | catalogued as rs766142792, COSV55643033; called by muse, mutect2, varscan2
- PLVAP | c.246C>T p.S82= | Silent (SNP) | VAF 24/404 reads (6%) | called by muse, mutect2
- PLXNA4 | c.5684G>A p.*1895= | Silent (SNP) | VAF 22/220 reads (10%) | catalogued as rs748399835, COSV58106334; called by muse, mutect2, varscan2
- PMFBP1 | c.1083G>A p.R361= | Silent (SNP) | VAF 38/384 reads (10%) | catalogued as rs1400137032; called by muse, mutect2, varscan2
- PPP1R13B | c.2818C>T p.L940= | Silent (SNP) | VAF 57/422 reads (14%) | called by muse, mutect2, varscan2
- PPP1R13B | c.2817C>T p.F939= | Silent (SNP) | VAF 57/421 reads (14%) | called by muse, mutect2, varscan2
- PPP1R3F | c.2061C>T p.P687= | Silent (SNP) | VAF 79/517 reads (15%) | called by muse, mutect2, varscan2
- PRR14 | c.1296T>C p.L432= | Silent (SNP) | VAF 18/384 reads (5%) | called by muse, mutect2
- PUS7L | c.333C>T p.I111= | Silent (SNP) | VAF 60/382 reads (16%) | catalogued as rs765288836, COSV61261932; called by muse, mutect2, varscan2
- SFTPD | c.12C>T p.F4= | Silent (SNP) | VAF 37/284 reads (13%) | catalogued as rs773088423; called by muse, mutect2, varscan2
- SLC17A8 | c.1455C>T p.L485= | Silent (SNP) | VAF 43/409 reads (11%) | called by muse, mutect2, varscan2
- SLC24A2 | c.1188G>A p.V396= | Silent (SNP) | VAF 28/334 reads (8%) | catalogued as rs749000302; called by muse, mutect2
- SRSF8 | c.45C>T p.T15= | Silent (SNP) | VAF 17/428 reads (4%) | called by muse, mutect2
- STEAP4 | c.216G>A p.K72= | Silent (SNP) | VAF 30/421 reads (7%) | catalogued as rs1317197073; called by muse, mutect2
- SYN1 | c.1749C>G p.G583= | Silent (SNP) | VAF 62/591 reads (10%) | called by muse, mutect2, varscan2
- TAOK1 | c.2739C>T p.N913= | Silent (SNP) | VAF 60/390 reads (15%) | called by muse, mutect2, varscan2
- TBX5 | c.1092G>A p.L364= | Silent (SNP) | VAF 30/410 reads (7%) | catalogued as rs1311014458; called by muse, mutect2
- TFAP2D | c.1320G>A p.E440= | Silent (SNP) | VAF 41/325 reads (13%) | called by muse, mutect2, varscan2
- TGFBR2 | c.1009C>T p.L337= | Silent (SNP) | VAF 38/534 reads (7%) | called by muse, mutect2
- TGM6 | c.450G>A p.E150= | Silent (SNP) | VAF 31/280 reads (11%) | catalogued as COSV52483631, COSV99172956; called by muse, mutect2, varscan2
- TLR4 | c.2278C>T p.L760= (on ENST00000355622 / NM_138554.5; = p.L720= on NM_003266.4) | Silent (SNP) | VAF 48/356 reads (13%) | catalogued as COSV100842931; called by muse, mutect2, varscan2
- TMEM200A | c.207G>T p.V69= | Silent (SNP) | VAF 36/350 reads (10%) | called by muse, mutect2, varscan2
- TRAV17 | c.87G>A p.Q29= | Silent (SNP) | VAF 27/200 reads (14%) | called by muse, mutect2, varscan2
- TSPAN16 | c.678A>C p.A226= | Silent (SNP) | VAF 55/236 reads (23%) | called by muse, mutect2, varscan2
- USP17L2 | c.405C>T p.A135= | Silent (SNP) | VAF 82/1311 reads (6%) | catalogued as rs1440996474; called by muse, mutect2
- VAMP3 | c.129C>T p.L43= | Silent (SNP) | VAF 44/370 reads (12%) | called by muse, mutect2, varscan2
- VCX3A | c.252C>T p.L84= | Silent (SNP) | VAF 28/673 reads (4%) | catalogued as rs1411900954; called by muse, mutect2
- VWA3A | c.2169C>T p.N723= | Silent (SNP) | VAF 32/250 reads (13%) | called by muse, mutect2, varscan2
- WASF1 | c.1278C>T p.P426= | Silent (SNP) | VAF 65/521 reads (12%) | catalogued as rs1168860181; called by muse, mutect2, varscan2
- WDR87 | c.1677C>T p.F559= | Silent (SNP) | VAF 16/389 reads (4%) | called by muse, mutect2
- ZNF615 | c.45G>A p.V15= | Silent (SNP) | VAF 38/288 reads (13%) | catalogued as COSV100944065; called by muse, mutect2, varscan2
- DNMT3A | c.448+20G>A | Intron (SNP) | VAF 47/350 reads (13%) | catalogued as rs776751263; called by muse, mutect2, varscan2
- FOXP1 | c.1652+456G>A | Intron (SNP) | VAF 58/425 reads (14%) | called by muse, mutect2, varscan2
- GRM5 | c.661+62370G>A | Intron (SNP) | VAF 22/230 reads (10%) | catalogued as COSV59594510; called by muse, mutect2, varscan2
- MRNIP | c.537+28C>T | Intron (SNP) | VAF 38/521 reads (7%) | called by muse, mutect2
- PALLD | c.*196G>A | 3'UTR (SNP) | VAF 23/225 reads (10%) | catalogued as rs896702235; called by muse, mutect2, varscan2
- PCGF3 | c.-21C>T | 5'UTR (SNP) | VAF 48/548 reads (9%) | catalogued as rs1424065142; called by muse, mutect2
- SWI5 | c.-96C>T | 5'UTR (SNP) | VAF 19/495 reads (4%) | catalogued as COSV60791472; called by muse, mutect2
- ZBBX | c.1880-6401C>T | Intron (SNP) | VAF 40/224 reads (18%) | catalogued as COSV56790040; called by muse, mutect2, varscan2
